Somatic mutation profile of tumor specimen ALCH-B0AN-TTP1-A (aliquot ALCH-B0AN-TTP1-A-1-0-D-A694-36) from ALCHEMIST case ALCH-B0AN, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 71.2 years (26,004 days).
Specimen ALCH-B0AN-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5e4557c3-91d8-46df-9c56-23f8d3207f90.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B0AN-NB1-A (Blood Derived Normal), aliquot ALCH-B0AN-NB1-A-1-0-D-A695-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/66ee844b-1fe7-4246-9a07-b9c701373b60

The open-access MAF lists 57 somatic variants for this specimen: 40 protein-altering or splice-affecting, 10 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Silent 10, Nonsense Mutation 3, Frame Shift Del 3, In Frame Del 2, 5'Flank 2, 3'UTR 2, Frame Shift Ins 2, 3'Flank 1, RNA 1, Splice Site 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2240_2257del p.L747_P753delinsS | In Frame Del (DEL) | VAF 47/268 reads (18%) | hotspot (GDC flag); catalogued as rs121913438, COSV51767961; ClinVar: drug response; called by mutect2, pindel, varscan2
- SMARCA4 | c.3575G>A p.R1192H | Missense Mutation (SNP) | VAF 22/63 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60785906, COSV60794673; called by muse, mutect2, varscan2
- KDM5C | c.202dup p.R68Pfs*7 | Frame Shift Ins (INS) | VAF 34/127 reads (27%) | catalogued as rs782600511; called by mutect2, pindel, varscan2
- LRRC27 | c.1477C>T p.R493C | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.183); catalogued as rs752575098, COSV63996310; called by muse, mutect2, varscan2
- PIWIL1 | c.49G>C p.E17Q | Missense Mutation (SNP) | VAF 15/142 reads (11%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.518); catalogued as COSV55351322; called by muse, mutect2, varscan2
- RELN | c.6890C>T p.S2297F | Missense Mutation (SNP) | VAF 67/228 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV104414862; called by muse, mutect2, varscan2
- SLC9C1 | c.2554G>A p.D852N | Missense Mutation (SNP) | VAF 46/201 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.439); catalogued as rs753060348; called by muse, mutect2, varscan2
- USH2A | c.5089G>A p.E1697K | Missense Mutation (SNP) | VAF 30/170 reads (18%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.787); catalogued as COSV56437782, COSV56448716; called by muse, mutect2, varscan2
- VIL1 | c.275G>A p.R92Q | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as rs765377445; called by muse, mutect2, varscan2
- WSB1 | c.367_368del p.Q123Efs*42 | Frame Shift Del (DEL) | VAF 95/477 reads (20%) | catalogued as rs768977031; called by mutect2, pindel, varscan2
- ZNF735 | c.555G>C p.L185F | Missense Mutation (SNP) | VAF 32/212 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1554366822, COSV70035668; called by muse, mutect2, varscan2
- ARHGEF37 | c.1755C>A p.D585E | Missense Mutation (SNP) | VAF 26/127 reads (20%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2, varscan2
- ASPM | c.5534A>G p.Q1845R | Missense Mutation (SNP) | VAF 96/361 reads (27%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- CCN4 | c.889C>T p.Q297* | Nonsense Mutation (SNP) | VAF 19/150 reads (13%) | called by muse, mutect2, varscan2
- COCH | c.77G>A p.G26E | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious, low confidence (0); called by muse, mutect2, varscan2
- COL6A6 | c.4870G>T p.G1624* | Nonsense Mutation (SNP) | VAF 41/179 reads (23%) | called by muse, mutect2, varscan2
- CTNND2 | c.985A>T p.I329F | Missense Mutation (SNP) | VAF 44/112 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- DDIAS | c.2587G>A p.E863K | Missense Mutation (SNP) | VAF 15/133 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); called by muse, mutect2, varscan2
- EIF4G2 | c.1521_1522insCA p.T508Qfs*41 | Frame Shift Ins (INS) | VAF 28/222 reads (13%) | called by mutect2, pindel, varscan2
- FAM135A | c.2423del p.L808* (on ENST00000370479 / NM_001351599.1; = p.L595* on NM_020819.4 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 21/135 reads (16%) | called by mutect2, pindel, varscan2
- FLG | c.6440G>A p.G2147E | Missense Mutation (SNP) | VAF 28/166 reads (17%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.686); called by muse, mutect2, varscan2
- GREB1L | c.1234G>A p.G412R | Missense Mutation (SNP) | VAF 57/176 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ICE2 | c.2632G>C p.D878H | Missense Mutation (SNP) | VAF 28/356 reads (8%) | SIFT tolerated (0.62); PolyPhen probably damaging (0.975); called by muse, mutect2
- KBTBD7 | c.600C>A p.F200L | Missense Mutation (SNP) | VAF 84/248 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KHDC4 | c.225G>C p.K75N | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- KL | c.481del p.S161Afs*138 | Frame Shift Del (DEL) | VAF 5/20 reads (25%) | called by mutect2, pindel
- KRT10 | c.873G>A p.M291I | Missense Mutation (SNP) | VAF 58/381 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.349); called by muse, mutect2, varscan2
- KRT6B | c.985G>T p.D329Y | Missense Mutation (SNP) | VAF 44/226 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KRT8 | c.668T>A p.F223Y | Missense Mutation (SNP) | VAF 31/148 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- MAGEA12 | c.338T>A p.M113K | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- METTL16 | c.13A>G p.K5E | Missense Mutation (SNP) | VAF 36/122 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- RNF145 | c.512_514del p.I171del (on ENST00000424310 / NM_001199383.2; = p.I199del on NM_144726.2) | In Frame Del (DEL) | VAF 100/921 reads (11%) | called by pindel, varscan2
- RPF2 | c.148A>G p.K50E | Missense Mutation (SNP) | VAF 29/129 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.513); called by muse, mutect2, varscan2
- SCAF8 | c.2785G>T p.G929* | Nonsense Mutation (SNP) | VAF 17/84 reads (20%) | called by muse, mutect2, varscan2
- SEMA6D | c.1172C>T p.S391L | Missense Mutation (SNP) | VAF 20/302 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.099); called by muse, mutect2
- SFTPA2 | c.133G>T p.D45Y | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRIO | c.3984G>C p.E1328D | Missense Mutation (SNP) | VAF 27/404 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.14); called by muse, mutect2
- VPS45 | c.1526G>A p.G509E | Missense Mutation (SNP) | VAF 16/196 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ZNF226 | c.1474G>A p.A492T | Missense Mutation (SNP) | VAF 35/124 reads (28%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF705A | c.140-2A>G p.X47_splice | Splice Site (SNP) | VAF 39/358 reads (11%) | called by muse, mutect2, varscan2
- DACT2 | c.2022C>T p.F674= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as rs1377986521, COSV64694567; called by muse, mutect2, varscan2
- HMGXB3 | c.900C>T p.Y300= (on ENST00000613459; = p.Y54= on NM_014983.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 18/141 reads (13%) | catalogued as rs552079525, COSV72211577; called by muse, mutect2, varscan2
- KLHL2 | c.825C>T p.L275= | Silent (SNP) | VAF 19/197 reads (10%) | called by muse, mutect2
- MUC16 | c.37098C>T p.L12366= | Silent (SNP) | VAF 23/75 reads (31%) | called by muse, mutect2, varscan2
- NWD1 | c.576C>T p.I192= | Silent (SNP) | VAF 14/33 reads (42%) | called by muse, mutect2, varscan2
- RAPH1 | c.1410G>A p.L470= (on ENST00000319170 / NM_213589.3; = p.L522= on NM_203365.4) | Silent (SNP) | VAF 17/133 reads (13%) | catalogued as rs139508191; called by muse, mutect2, varscan2
- RBBP5 | c.510C>T p.N170= | Silent (SNP) | VAF 20/65 reads (31%) | catalogued as rs746302142, COSV52705127; called by mutect2, varscan2
- SCAF8 | c.2784G>T p.P928= | Silent (SNP) | VAF 17/84 reads (20%) | catalogued as COSV65793532; called by muse, mutect2, varscan2
- SCNN1B | c.159C>T p.F53= | Silent (SNP) | VAF 18/96 reads (19%) | catalogued as rs749106839; ClinVar: uncertain significance; called by muse, varscan2
- XPO7 | c.540T>G p.S180= | Silent (SNP) | VAF 14/223 reads (6%) | called by muse, mutect2
- AP000769.5 | chr11:65499183 del AT | 5'Flank (DEL) | VAF 22/114 reads (19%) | called by pindel, varscan2
- DUSP13 | c.*164C>T | 3'UTR (SNP) | VAF 7/33 reads (21%) | called by muse, mutect2, varscan2
- MRPL20 | chr1:1399597 G>T | 3'Flank (SNP) | VAF 16/47 reads (34%) | called by muse, mutect2, varscan2
- NACA | c.71-4401T>C | Intron (SNP) | VAF 31/248 reads (13%) | called by muse, mutect2, varscan2
- NBPF25P | n.856G>A | RNA (SNP) | VAF 79/365 reads (22%) | catalogued as rs1332852823; called by muse, mutect2, varscan2
- PMS2 | chr7:6009098 C>T | 5'Flank (SNP) | VAF 14/42 reads (33%) | called by muse, varscan2
- PPP6R3 | c.*1806C>A | 3'UTR (SNP) | VAF 37/157 reads (24%) | called by muse, mutect2, varscan2
